Gene-level copy-number profile of tumor specimen C3L-02349-01 from CPTAC case C3L-02349, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 81.0 years (29,600 days).
Specimen C3L-02349-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 93e6a835-b958-4829-9388-a0b801381e3d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02349-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,261 have no estimate.
https://portal.gdc.cancer.gov/files/43dcb72a-862f-4e9d-afed-2abf6c69993e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 1: 21,080; copy number 2: 21,524; copy number 3: 10,429; copy number 4: 2,731; copy number 5: 1,637; copy number 6: 933.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 6 genes (within-gene range 0–1): RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1.
- chr3:73,999,805–74,136,892, 3 genes: LINC02047, AC016930.1, AKR1B1P2.
- chr5:148,088,125–148,383,907, 1 gene (within-gene range 0–1): AC011346.1.
- chr5:148,268,180–148,677,235, 10 genes: SPINK13, PGBD4P3, SPINK7, SPINK9, AC091948.1, FBXO38, Metazoa_SRP, AC114939.1, HTR4, AC008627.1.
- chr6:114,477,350–114,488,752, 1 gene: AL138830.2.
- chr14:105,620,506–105,673,314, 7 genes (within-gene range 0–1): IGHG4, MIR8071-1, IGHG2, MIR8071-2, COPDA1, IGHGP, ELK2AP.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,570 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:266,855–675,265, 19 genes, copy number 5: AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6, AC114498.1, MTND1P23, MTND2P28, MTCO1P12, AC114498.2, MTCO2P12, MTATP8P1, MTATP6P1, MTCO3P12, WBP1LP6.
- chr1:119,140,391–121,580,524, 71 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr1:224,114,111–224,779,335, 20 genes, copy number 5: FBXO28, AC092809.3, DEGS1, SNORA72, AC092809.2, AC092809.4, NVL, MIR320B2, AC092809.1, RNU6-1008P, CNIH4, WDR26, MIR4742, CNIH3, AKR1B1P1, CNIH3-AS2, DNAJB6P6, AL596330.1, CNIH3-AS1, LINC02813.
- chr1:248,906,196–248,937,043, 3 genes, copy number 5: PGBD2, RNU6-1205P, RPL23AP25.
- chr2:17,122,841–74,970,128, 1,024 genes, copy number 5 (broad region; genes not listed).
- chr2:75,455,994–78,438,921, 34 genes, copy number 5: GAPDHP57, EVA1A, AC007099.2, AC007099.3, AC007099.1, AC005034.1, U3, MRPL19, SUPT4H1P1, GCFC2, AC005034.3, AC005034.5, AC005034.2, AC005034.6, AC005034.4, AC110614.1, SUCLA2P2, AC073091.1, PNPP1, USP21P2, RN7SKP203, RN7SKP164, LRRTM4, RNA5SP98, AC079117.1, LRRTM4-AS1, AC013716.1, AC012494.1, AC084149.1, RPL38P2, LINC01851, AC012494.2, CYCSP6, AC064872.1.
- chr2:79,185,231–84,460,045, 40 genes, copy number 5 (within-gene range 4–5): CTNNA2, AC011754.2, CTNNA2-AS1, AC010975.1, GNA13P1, RNU6-561P, MIR4264, MIR8080, AC016716.1, RBM7P1, LRRTM1, AC008067.1, AC012355.1, ANKRD11P1, CHMP4AP1, LINC01815, RNA5SP99, AC013262.1, RN7SL201P, AC079896.1, LYARP1, RNU6-685P, Y_RNA, AC010105.1, RBX1P1, MTND4P25, MTND5P27, MTND6P7, MTCYBP7, AC098817.1, DHFRP3, AC138623.1, LINC01809, RPL37P10, RNU6-1312P, CRLF3P3, ST6GALNAC2P1, FUNDC2P2, AC106874.1, SUCLG1.
- chr3:123,610,049–123,884,332, 1 gene, copy number 5 (within-gene range 3–5): MYLK.
- chr3:123,814,077–198,123,232, 1,325 genes, copy number 5–6 (broad region; genes not listed).
- chr5:17,089,296–17,217,047, 5 genes, copy number 5: BASP1-AS1, AC026790.1, Y_RNA, RNA5SP180, DCAF13P2.
- chr6:61,574,328–62,461,503, 5 genes, copy number 5: MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1, DHFRP5.
- chr9:60,914,407–61,666,386, 17 genes, copy number 6: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1, AL935212.2.
- chr11:102,295,060–102,295,806, 1 gene, copy number 5: AP000942.1.
- chr17:72,290,091–72,644,490, 5 genes, copy number 5: LINC00511, LINC02003, AC007639.1, RPL32P33, AC080037.2.

Autosomal genes at a single copy (total copy number 1): 18,847. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
